Somatic mutation profile of tumor specimen TCGA-55-7911-01A (aliquot TCGA-55-7911-01A-11D-2167-08) from TCGA case TCGA-55-7911, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.5 years (25,746 days).
Specimen TCGA-55-7911-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2706af2-2c35-4684-83b5-ecf3eabdbde7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7911-10A (Blood Derived Normal), aliquot TCGA-55-7911-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fce00398-a6be-4c15-80d3-f9fd3c7c5056

The open-access MAF lists 252 somatic variants for this specimen: 191 protein-altering or splice-affecting, 53 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 161, Silent 53, Nonsense Mutation 11, Splice Site 7, RNA 5, Frame Shift Del 5, Splice Region 4, Frame Shift Ins 2, In Frame Del 1, Intron 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP152 | c.2038C>T p.Q680* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as rs886039327, COSV57857964; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PHEX | c.1900-1G>A p.X634_splice | Splice Site (SNP) | VAF 9/76 reads (12%) | catalogued as rs755406730, COSV65074478; ClinVar: likely pathogenic; called by mutect2, varscan2
- TP53 | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs786201419, COSV52676427, COSV52842986, COSV53108952; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.2267A>T p.H756L | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.05); catalogued as COSV52705102; called by muse, mutect2, varscan2
- ABAT | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs775462540, COSV51621435, COSV51628035; called by muse, mutect2, varscan2
- ABCA12 | c.4097T>G p.L1366R (on ENST00000272895 / NM_173076.3; = p.L1048R on NM_015657.3) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55953098; called by muse, mutect2, varscan2
- ACVR1C | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1259517767, COSV54644695, COSV54646079; called by muse, mutect2, varscan2
- ADAD1 | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.36); catalogued as COSV56642409, COSV56643144; called by muse, mutect2, varscan2
- ADGRL4 | c.1171C>A p.L391M | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.264); catalogued as COSV66060280; called by muse, mutect2, varscan2
- ADIPOQ | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); catalogued as rs200546423, COSV57858697; called by muse, mutect2, varscan2
- AHNAK | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as COSV57207876, COSV99948362; called by muse, mutect2, varscan2
- ALDH1L1 | c.1378G>T p.D460Y | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56412113; called by muse, mutect2, varscan2
- ALG1L | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs373951263, COSV61075462; called by mutect2, varscan2
- ANKRD28 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67517407; called by muse, mutect2
- ANKRD44 | c.2632A>C p.M878L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV56551332; called by muse, mutect2, varscan2
- ARHGAP24 | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67838072; called by muse, mutect2, varscan2
- ARHGEF17 | c.6050C>T p.P2017L | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55230904; called by muse, mutect2, varscan2
- ARMCX2 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 27/147 reads (18%) | catalogued as COSV100168223, COSV57529518; called by muse, mutect2, varscan2
- ARSH | c.1241G>T p.R414M | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as rs766897149, COSV66962701; called by muse, mutect2, varscan2
- ATP2B2 | c.3200G>T p.G1067V (on ENST00000352432; = p.G1033V on NM_001683.5) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV59492249; called by muse, mutect2, varscan2
- ATXN3L | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.529); catalogued as COSV66075382, COSV66076328; called by muse, mutect2, varscan2
- BGN | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782654370, COSV59036254; called by muse, mutect2, varscan2
- BRWD3 | c.3125A>T p.E1042V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100956422; called by muse, mutect2, varscan2
- C6orf118 | c.735C>A p.H245Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV57812313, COSV57813075; called by muse, mutect2, varscan2
- CAD | c.3511C>T p.P1171S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV53027842, COSV99255563; called by muse, mutect2, varscan2
- CALCA | c.86+1G>C p.X29_splice | Splice Site (SNP) | VAF 7/81 reads (9%) | catalogued as COSV59027589; called by muse, mutect2, varscan2
- CARD11 | c.332C>A p.P111H | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62716895; called by muse, varscan2
- CARD16 | c.89T>G p.L30* | Nonsense Mutation (SNP) | VAF 55/250 reads (22%) | catalogued as COSV65212839; called by muse, mutect2, varscan2
- CD1E | c.155A>T p.H52L | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV63770444; called by muse, mutect2, varscan2
- CD69 | c.332A>T p.N111I | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV57302501, COSV57303192; called by muse, mutect2, varscan2
- CDC42EP4 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as rs780241894, COSV59962323; called by muse, mutect2, varscan2
- CDH2 | c.1273G>C p.G425R | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52274748, COSV52293811; called by muse, mutect2, varscan2
- CDH6 | c.130A>C p.S44R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.104); catalogued as COSV54066590; called by muse, mutect2, varscan2
- CHRNA1 | c.969G>C p.M323I (on ENST00000261007 / NM_001039523.3; = p.M298I on NM_000079.4) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); catalogued as rs1377577817, COSV53682162, COSV53683472; called by muse, mutect2, varscan2
- CHRNG | c.320T>A p.V107E | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as CM062517, COSV99286090; called by muse, mutect2, varscan2
- CHST5 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.281); catalogued as COSV60337922; called by muse, mutect2, varscan2
- CLEC4A | c.65A>G p.N22S | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs36113649; called by muse, mutect2, varscan2
- COL4A4 | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61630562, COSV61636519; called by muse, mutect2, varscan2
- CPAMD8 | c.1484A>T p.Y495F (on ENST00000651564; = p.Y448F on NM_015692.5) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.771); catalogued as COSV52232683; called by muse, mutect2
- CSNK2A2 | c.266T>G p.L89R | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52641436; called by muse, mutect2, varscan2
- CTSG | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53534999; called by muse, mutect2, varscan2
- CYP8B1 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60225918; called by muse, mutect2, varscan2
- DDX1 | c.1361G>T p.R454I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51838807; called by muse, mutect2, varscan2
- DGKK | c.530C>A p.P177Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV65706824; called by muse, mutect2
- DHX35 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV52668733; called by muse, mutect2
- EAF2 | c.543T>A p.D181E | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV56543815; called by muse, mutect2, varscan2
- EDNRB | c.1231G>T p.V411L (on ENST00000377211 / NM_001201397.1; = p.V321L on NM_000115.5) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.674); catalogued as COSV100526983; called by muse, mutect2
- EHMT2 | c.3409G>A p.A1137T | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1331624854, COSV57666506; called by muse, mutect2
- EML4 | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs776611036, COSV59295358; called by muse, mutect2, varscan2
- EPHA5 | c.1849C>G p.L617V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.899); catalogued as COSV56675105, COSV99900678; called by muse, mutect2
- EPS8L2 | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 2/22 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59347311; called by muse, mutect2
- F8 | c.3793C>A p.P1265T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV64271023, COSV64278886; called by muse, mutect2, varscan2
- FAM47C | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.307); catalogued as COSV63725008; called by muse, mutect2, varscan2
- FHOD3 | c.1668del p.D558Ifs*27 (on ENST00000359247 / NM_001281739.3; = p.D575Ifs*27 on NM_025135.5) | Frame Shift Del (DEL) | VAF 40/237 reads (17%) | catalogued as COSV99942895; called by mutect2, pindel, varscan2
- FMO3 | c.617C>G p.T206R | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV100882536, COSV63007561; called by muse, mutect2, varscan2
- FOCAD | c.3315C>G p.L1105= | Splice Region (SNP) | VAF 7/72 reads (10%) | catalogued as COSV58095698; called by muse, mutect2
- FOXK2 | c.1336G>T p.A446S | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV58877772; called by muse, mutect2, varscan2
- FRMPD1 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66699642; called by muse, mutect2, varscan2
- GABRG3 | c.1148C>A p.P383Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); catalogued as rs762414546, COSV61513013; called by muse, mutect2, varscan2
- GAD2 | c.1702C>A p.H568N | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as COSV52153352; called by muse, mutect2, varscan2
- GALNT10 | c.1160C>G p.A387G | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.68); PolyPhen benign (0.024); catalogued as COSV51722325; called by muse, mutect2, varscan2
- GAS2L3 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV57155891, COSV57156532; called by muse, mutect2, varscan2
- GDF6 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315257881, COSV54625295, COSV54625350; called by muse, mutect2
- GLDC | c.1748T>G p.V583G | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV58677538; called by muse, mutect2, varscan2
- GPR148 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59307864; called by muse, mutect2, varscan2
- GPR171 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.738); catalogued as COSV56372974; called by muse, mutect2, varscan2
- GUCY2F | c.2159C>A p.A720D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99485523; called by muse, mutect2, varscan2
- HK1 | c.2487G>C p.R829S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53855537; called by muse, mutect2, varscan2
- HNRNPA3 | c.740-2A>T p.X247_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as COSV66820717; called by muse, mutect2
- HNRNPUL1 | c.599A>C p.E200A | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV54561129; called by muse, mutect2, varscan2
- HOXB3 | c.1069G>T p.G357C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV100290793; called by muse, mutect2, varscan2
- HOXD13 | c.301G>C p.A101P | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.898); catalogued as rs750927181, COSV66832413; called by muse, mutect2, varscan2
- IGLL5 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV66535598; called by muse, mutect2
- IGSF1 | c.2101C>A p.L701I | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63836697; called by muse, mutect2, varscan2
- INSRR | c.2568G>T p.L856F | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.27); catalogued as COSV63871692; called by muse, mutect2, varscan2
- IRF6 | c.523C>G p.P175A | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV65418863; called by muse, mutect2
- ITGA4 | c.1591C>A p.P531T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.057); catalogued as COSV99276722; called by muse, mutect2, varscan2
- ITPRID1 | c.1657G>T p.V553F | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.487); catalogued as COSV60071898; called by muse, mutect2, varscan2
- KCNJ6 | c.797C>A p.T266K | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); catalogued as COSV55711129, COSV99900269; called by muse, mutect2, varscan2
- KIAA1109 | c.6059C>G p.T2020R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV52666322; called by muse, mutect2, varscan2
- KIAA1549L | c.2420C>T p.A807V (on ENST00000321505; = p.A1104V on NM_012194.3) | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV55771136, COSV99039798; called by muse, mutect2
- KIF17 | c.2813T>A p.L938H | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.707); catalogued as COSV56116938; called by muse, mutect2, varscan2
- KLHDC8A | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV65678468; called by muse, mutect2
- KMT5B | c.257G>C p.S86T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); catalogued as COSV58564728; called by muse, mutect2, varscan2
- KNTC1 | c.4523C>A p.T1508K | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as COSV61079369; called by muse, mutect2, varscan2
- KRAS | c.262A>T p.K88* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV55596097, COSV56097638; called by muse, mutect2, varscan2
- LRPPRC | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53235918, COSV53239322; called by muse, mutect2, varscan2
- LRRTM1 | c.736G>T p.A246S | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV54439470, COSV54445260; called by muse, mutect2, varscan2
- MCM5 | c.1885C>T p.Q629* | Nonsense Mutation (SNP) | VAF 18/87 reads (21%) | catalogued as COSV53345458; called by muse, mutect2, varscan2
- ME3 | c.547G>T p.V183L | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as rs748371206, COSV60164477; called by muse, mutect2, varscan2
- MED10 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV55385854; called by muse, mutect2, varscan2
- MGAT5 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56095046; called by muse, mutect2, varscan2
- MIA3 | c.4593G>T p.E1531D | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV60511145; called by muse, mutect2, varscan2
- MKRN2 | c.975dup p.A326Sfs*3 | Frame Shift Ins (INS) | VAF 6/49 reads (12%) | catalogued as rs1377010344; called by mutect2, pindel, varscan2
- MTREX | c.1513G>T p.D505Y | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57924143, COSV57924570; called by muse, mutect2, varscan2
- MYO18B | c.4817A>G p.Q1606R | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV59129199; called by muse, mutect2
- NCKAP5 | c.4842A>T p.K1614N | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.181); catalogued as COSV58434886, COSV58435313; called by muse, mutect2
- NCKAP5 | c.1286G>T p.C429F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1185487004, COSV100493934; called by muse, mutect2, varscan2
- NES | c.200T>A p.V67D | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV63960590; called by muse, mutect2, varscan2
- NFRKB | c.1511+1G>T p.X504_splice (on ENST00000446488 / NM_001143835.2; = p.X529_splice on NM_006165.3) | Splice Site (SNP) | VAF 14/83 reads (17%) | catalogued as COSV100452062; called by muse, mutect2, varscan2
- NMNAT2 | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.138); catalogued as rs1558105428, COSV54266856; called by muse, mutect2, varscan2
- NOL4 | c.398del p.K133Rfs*19 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | catalogued as COSV52359432; called by mutect2, pindel, varscan2
- NPY2R | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV61527622; called by muse, mutect2, varscan2
- NRBP1 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99275242; called by muse, mutect2, varscan2
- NTRK3 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV58114623, COSV58142385; called by muse, mutect2, varscan2
- OR10K2 | c.526C>G p.H176D | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59220699; called by muse, mutect2
- OR2T3 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV62082060; called by mutect2, varscan2
- OR4M1 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV60060098; called by muse, mutect2, varscan2
- OR5AS1 | c.577C>A p.Q193K | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57981224; called by muse, mutect2, varscan2
- OR5L1 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100450207; called by muse, mutect2, varscan2
- OR5M1 | c.281A>T p.Y94F | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV73202012; called by muse, mutect2, varscan2
- OR5T2 | c.895G>T p.V299L | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as COSV57588355; called by muse, mutect2, varscan2
- OTOF | c.1015A>G p.M339V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV55499063; called by muse, mutect2, varscan2
- PADI3 | c.498T>G p.N166K | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.272); catalogued as COSV64934170; called by muse, mutect2, varscan2
- PAIP1 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as COSV59085526; called by muse, mutect2, varscan2
- PCDHGB3 | c.2222C>A p.P741H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV53917901; called by muse, mutect2, varscan2
- PDCD11 | c.5493G>T p.M1831I | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.097); catalogued as COSV53294727; called by muse, mutect2, varscan2
- PDHA1 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58827438; called by muse, mutect2, varscan2
- PGBD1 | c.2110A>T p.I704L | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV52552082; called by muse, mutect2, varscan2
- PLSCR4 | c.32A>T p.Q11L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV61607620; called by muse, mutect2, varscan2
- PLXNC1 | c.2298C>A p.I766= | Splice Region (SNP) | VAF 16/95 reads (17%) | catalogued as COSV51571854; called by muse, mutect2, varscan2
- POLE | c.4408A>T p.M1470L | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV57676873; called by muse, mutect2
- POLR1A | c.4571G>T p.W1524L | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55690717; called by muse, mutect2, varscan2
- PPFIA2 | c.1192C>A p.Q398K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV61025021; called by muse, mutect2, varscan2
- PPP1R12B | c.2195C>T p.T732M | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs143792888; called by muse, mutect2
- PRPF4B | c.1277G>C p.R426T | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV100528276, COSV61783682; called by muse, mutect2
- PTPRH | c.989A>T p.Y330F | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV54743813; called by muse, mutect2, varscan2
- RAB39A | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs549198709, COSV57694599; called by muse, mutect2, varscan2
- RABGGTA | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53769793; called by muse, mutect2, varscan2
- REG1B | c.138C>A p.Y46* | Nonsense Mutation (SNP) | VAF 41/159 reads (26%) | catalogued as COSV59304872; called by muse, mutect2, varscan2
- RGS8 | c.100C>G p.L34V (on ENST00000367556 / NM_001369564.2; = p.L52V on NM_033345.3) | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.225); catalogued as COSV51115463; called by muse, mutect2
- RHOBTB2 | c.1575G>A p.M525I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV52570182; called by muse, mutect2, varscan2
- RIPK1 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193251671, COSV52528533; called by muse, mutect2, varscan2
- RTL4 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 20/107 reads (19%) | catalogued as COSV61205857, COSV61207181; called by muse, mutect2, varscan2
- RXFP2 | c.873T>G p.N291K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53634089; called by muse, mutect2, varscan2
- SCN3A | c.4861C>G p.R1621G | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51802367, COSV51805129; called by muse, mutect2, varscan2
- SEMA3B | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV57112968; called by muse, mutect2, varscan2
- SEMA6D | c.3049G>A p.V1017M (on ENST00000316364 / NM_153618.2; = p.V955M on NM_020858.2) | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs371308825, COSV60374584; called by muse, mutect2, varscan2
- SERPIND1 | c.1292G>T p.R431M | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV53137910; called by muse, mutect2
- SGMS1 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV62369802; called by muse, mutect2, varscan2
- SI | c.2485G>T p.D829Y | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs1433341918, COSV52270976; called by muse, mutect2, varscan2
- SLC17A6 | c.1484C>A p.A495E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV54134551; called by muse, mutect2, varscan2
- SLCO5A1 | c.518G>T p.C173F | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1450237082, COSV52656042; called by muse, mutect2, varscan2
- SLIT3 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60597916; called by muse, mutect2
- SMOC1 | c.403T>A p.Y135N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62760091; called by muse, mutect2, varscan2
- SPATA31E1 | c.2111A>G p.D704G | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1464020805, COSV57790230; called by muse, mutect2, varscan2
- SPOCK1 | c.856A>T p.N286Y | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56441335; called by muse, mutect2
- SPTAN1 | c.6685C>G p.L2229V | Missense Mutation (SNP) | VAF 40/588 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV63986039, COSV63989046; called by muse, mutect2
- SRSF1 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 83/316 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV51964452; called by muse, mutect2, varscan2
- SSMEM1 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52833235; called by muse, mutect2, varscan2
- STAB1 | c.6961T>C p.C2321R | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100195371; called by muse, mutect2
- STAB2 | c.3474+2C>T p.X1158_splice | Splice Site (SNP) | VAF 6/63 reads (10%) | catalogued as COSV66336495; called by muse, mutect2
- SYNE1 | c.10136G>T p.R3379L (on ENST00000367255 / NM_182961.4; = p.R3386L on NM_033071.3) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.341); catalogued as COSV54936646, COSV54980914; called by muse, mutect2, varscan2
- SYT10 | c.62C>A p.T21N | Missense Mutation (SNP) | VAF 91/300 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV57338706; called by muse, mutect2, varscan2
- TAS2R42 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as COSV62084469; called by muse, mutect2
- TCN1 | c.1074C>A p.F358L | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV57252645; called by muse, mutect2, varscan2
- TCP11L2 | c.835T>G p.S279A | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.517); catalogued as COSV54429318; called by muse, mutect2, varscan2
- TEDC1 | c.588C>T p.I196= | Splice Region (SNP) | VAF 6/40 reads (15%) | catalogued as rs782524294, COSV58153568; called by muse, varscan2
- THSD4 | c.2387G>T p.S796I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55964772; called by muse, mutect2, varscan2
- TKTL1 | c.1264C>A p.P422T | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54212027; called by muse, mutect2, varscan2
- TLE1 | c.1459G>A p.V487M | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs1229709305, COSV64719922; called by muse, mutect2, varscan2
- TMCO6 | c.1009C>A p.R337S | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52799329; called by muse, mutect2, varscan2
- TMED10 | c.365T>A p.V122E | Missense Mutation (SNP) | VAF 57/262 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV57847271; called by muse, mutect2, varscan2
- TMPRSS15 | c.1857C>A p.N619K | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV53036780; called by muse, mutect2, varscan2
- TRIM67 | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV64158442; called by muse, mutect2
- TRPA1 | c.593G>C p.G198A | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as COSV51557642; called by muse, mutect2, varscan2
- UBE4B | c.3596T>C p.I1199T (on ENST00000343090 / NM_001105562.3; = p.I1070T on NM_006048.5) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.111); catalogued as rs1411650159, COSV53528950; called by muse, mutect2, varscan2
- USH2A | c.9815C>A p.P3272Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM081850, COSV56343205; called by muse, mutect2, varscan2
- USP34 | c.4549-2A>C p.X1517_splice | Splice Site (SNP) | VAF 15/71 reads (21%) | catalogued as COSV68399572; called by mutect2, varscan2
- USP9X | c.7501C>A p.P2501T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV61067265; called by muse, mutect2
- WDR13 | c.198C>A p.Y66* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV54331224, COSV99489400; called by muse, mutect2, varscan2
- WDR13 | c.834G>T p.V278= | Splice Region (SNP) | VAF 8/34 reads (24%) | catalogued as COSV54331242; called by mutect2, varscan2
- ZDHHC12 | c.349C>A p.R117S | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as COSV52575692; called by muse, mutect2, varscan2
- ZFHX4 | c.3806A>G p.H1269R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV50638719; called by muse, mutect2, varscan2
- ZIC1 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1357156737, COSV51551988, COSV99291965; called by muse, mutect2
- ZIC5 | c.1640G>T p.S547I | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57437118; called by muse, mutect2, varscan2
- ZIK1 | c.1226G>T p.C409F | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56736712; called by muse, mutect2, varscan2
- ZMYM3 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.271); catalogued as COSV100078298; called by muse, mutect2
- ZNF19 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.142); catalogued as COSV55507237; called by muse, mutect2, varscan2
- ZNF221 | c.1268A>T p.K423I | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); catalogued as COSV52108670; called by muse, mutect2, varscan2
- ZNF382 | c.1118C>A p.T373K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV53086879; called by muse, mutect2, varscan2
- ZNF521 | c.3307G>T p.A1103S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755213954, COSV64124019, COSV64127897; called by muse, mutect2, varscan2
- CCDC178 | c.1687del p.A563Hfs*8 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- CNTN6 | c.665dup p.M222Ifs*5 | Frame Shift Ins (INS) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- IGF2R | c.1576_1579del p.G526Rfs*30 | Frame Shift Del (DEL) | VAF 14/104 reads (13%) | called by mutect2, pindel, varscan2
- MDGA2 | c.2988_2989+1delinsTA p.X996_splice (on ENST00000399232 / NM_001113498.2; = p.X698_splice on NM_182830.4) | Splice Site (DEL) | VAF 9/45 reads (20%) | called by pindel, varscan2*
- NPHP1 | c.1942_1950del p.L648_S650del (on ENST00000393272 / NM_207181.4; = p.L649_S651del on NM_000272.5) | In Frame Del (DEL) | VAF 19/79 reads (24%) | called by mutect2, pindel, varscan2
- TRBV30 | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF761 | c.2087del p.G696Afs*77 | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | called by mutect2, varscan2
- AC005833.1 | c.1578C>G p.T526= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV52895709, COSV99363309; called by muse, mutect2, varscan2
- ACSBG1 | c.828C>T p.C276= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV51904360; called by muse, mutect2
- AKAP4 | c.2526C>A p.A842= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV62073993; called by muse, mutect2, varscan2
- APP | c.1536C>T p.F512= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs1476363021, COSV60993526; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1329C>A p.A443= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV63437344; called by muse, mutect2, varscan2
- ATP7A | c.480T>C p.C160= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as COSV58444055; called by muse, mutect2, varscan2
- ATRX | c.2679C>G p.G893= | Silent (SNP) | VAF 43/234 reads (18%) | catalogued as COSV64873586; called by muse, mutect2, varscan2
- AURKC | c.795G>T p.G265= (on ENST00000302804 / NM_001015878.2; = p.G231= on NM_003160.3) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV57137399; called by muse, mutect2, varscan2
- BPIFB3 | c.193C>A p.R65= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV64956996, COSV64957549; called by muse, mutect2, varscan2
- C1orf109 | c.249C>A p.I83= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as COSV59238118; called by muse, mutect2
- CAMTA1 | c.3045G>T p.G1015= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV57888208; called by muse, mutect2, varscan2
- CBLN1 | c.567G>T p.L189= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV99535780; called by muse, mutect2, varscan2
- CLEC1A | c.498T>G p.L166= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV59531306; called by muse, mutect2, varscan2
- CLP1 | c.405C>T p.L135= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100239646, COSV100239833, COSV57054118; called by mutect2, varscan2
- CXCR2 | c.279C>A p.A93= | Silent (SNP) | VAF 29/151 reads (19%) | catalogued as COSV59280089, COSV59280489; called by muse, mutect2, varscan2
- DIS3 | c.480G>A p.L160= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs778838980, COSV58321495; called by mutect2, varscan2
- DLX6 | c.666T>C p.F222= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV50293039; called by muse, mutect2, varscan2
- DYNC1H1 | c.8022T>C p.Y2674= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV64135249; called by muse, mutect2, varscan2
- FAM126B | c.807A>T p.L269= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV53771930; called by muse, mutect2, varscan2
- FBXL4 | c.141C>T p.L47= | Silent (SNP) | VAF 32/149 reads (21%) | catalogued as rs267601175, COSV57745734; called by muse, mutect2, varscan2
- GABRG3 | c.114G>A p.L38= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV61513008; called by muse, mutect2, varscan2
- GCC1 | c.1641G>A p.Q547= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV58462099; called by muse, mutect2, varscan2
- HCFC1 | c.3282C>T p.A1094= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs372258214, COSV60070491; called by muse, mutect2, varscan2
- ILRUN | c.387G>C p.V129= | Silent (SNP) | VAF 43/232 reads (19%) | catalogued as COSV64989648; called by muse, mutect2, varscan2
- ITIH6 | c.744T>C p.V248= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV54487604; called by muse, mutect2, varscan2
- KCNT1 | c.939C>G p.V313= (on ENST00000488444; = p.V332= on NM_020822.3) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV53698214, COSV53704547; called by muse, varscan2
- KIF1A | c.2961G>T p.L987= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV57485408; called by muse, mutect2, varscan2
- MAGEB4 | c.465T>A p.S155= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV66775482; called by muse, mutect2, varscan2
- MROH1 | c.4434G>A p.K1478= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs1193015728; called by muse, mutect2, varscan2
- MYH2 | c.705C>T p.N235= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs201018335, COSV55434048; ClinVar: likely benign; called by muse, mutect2, varscan2
- NAA10 | c.264G>A p.Q88= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV64169523; called by muse, mutect2
- OR5L1 | c.729C>T p.S243= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as COSV100450205; called by muse, mutect2, varscan2
- OR6N2 | c.414C>T p.T138= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs748195086, COSV59410772; called by muse, mutect2, varscan2
- PACS2 | c.432A>G p.Q144= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1555408141, COSV57650975; called by muse, mutect2, varscan2
- PCDH10 | c.2136A>G p.L712= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV52090069; called by muse, varscan2
- PIGS | c.498G>A p.R166= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV52023982; called by muse, mutect2
- PLXNA4 | c.2463C>T p.F821= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs769546204, COSV58113685; called by muse, mutect2, varscan2
- PRDM9 | c.519G>A p.K173= | Silent (SNP) | VAF 42/133 reads (32%) | catalogued as COSV57004200; called by muse, varscan2
- RAI2 | c.1530C>A p.S510= | Silent (SNP) | VAF 61/386 reads (16%) | catalogued as COSV58963561; called by muse, mutect2, varscan2
- RSPRY1 | c.1498C>T p.L500= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV68027422; called by muse, mutect2
- RTL8B | c.261G>A p.E87= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV66954188; called by muse, mutect2, varscan2
- RTL8C | c.141G>T p.T47= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV57059859; called by muse, mutect2, varscan2
- RTN1 | c.1878C>T p.Y626= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV50720210; called by muse, mutect2, varscan2
- SEMA3A | c.360A>T p.V120= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV54864847; called by muse, mutect2, varscan2
- SLC22A12 | c.27C>T p.L9= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as rs1356621309, COSV60571387; called by muse, mutect2, varscan2
- SLC6A2 | c.1056C>T p.I352= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as COSV54914698; called by muse, mutect2, varscan2
- SLIT2 | c.429A>T p.P143= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV56565556; called by muse, mutect2, varscan2
- SMU1 | c.1200C>G p.V400= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV68139693; called by muse, mutect2, varscan2
- SPINT1 | c.342C>A p.A114= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SPRED2 | c.126G>T p.G42= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs768122400, COSV62691923; called by muse, mutect2, varscan2
- SRRT | c.642G>C p.R214= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV61451562; called by muse, mutect2, varscan2
- TMEM31 | c.357C>A p.I119= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as COSV60327397; called by muse, mutect2, varscan2
- TOB1 | c.423C>T p.P141= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs142180537; called by muse, mutect2, varscan2
- FOLH1B | n.1014C>A | RNA (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- GLRXP3 | n.201G>A | RNA (SNP) | VAF 17/174 reads (10%) | called by muse, mutect2
- IGKV1OR22-5 | n.141C>A | RNA (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85721A>C | Intron (SNP) | VAF 20/86 reads (23%) | catalogued as COSV72275891; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791114 G>T | 5'Flank (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- SNORD115-23 | n.18C>A | RNA (SNP) | VAF 44/285 reads (15%) | catalogued as rs1208743832; called by muse, mutect2, varscan2
- TRIM8 | c.*563G>T | 3'UTR (SNP) | VAF 10/73 reads (14%) | catalogued as COSV56659949; called by muse, mutect2, varscan2
- WASF4P | n.127C>A | RNA (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
